CCDI case PBCMZG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/83efbf12-995d-453a-a196-7a5a76e541e5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sertoli-Leydig cell tumor, poorly differentiated: ICD-O-3 morphology code: 8631/3; Tissue or organ of origin: Ovary; Age at diagnosis: 15.2 years (5,551 days).

Biospecimens (2 samples)
- Sample 0DVZ0M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ16: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
